CPTAC case C3N-00497 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d55de89b-c5bd-4901-9de9-fecaae0f9cfd

Demographics
Sex at birth: female; Race: white; Year of birth: 1951; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Middle lobe, lung; Age at diagnosis: 65.0 years (23,739 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2b; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,812 days (5.0 years); Progression or recurrence: no; Days to last follow up: 1,812 days (5.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5 cm (a second GDC size field records 2.5 cm); Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 10; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 369 days (1.0 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 740 days (2.0 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,048 days (2.9 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 1.
- Days to follow up: 1,048 days (2.9 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 1.
- Days to follow up: 1,439 days (3.9 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 1.
- Days to follow up: 1,812 days (5.0 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 1.

Other clinical attributes
- Weight: 53 kg; Height: 159 cm; BMI: 20.96.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 31; Cigarettes per day: 20; Tobacco smoking onset year: 1981; Tobacco smoking quit year: 2012; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 31.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00497-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -31 days; Initial weight: 445 mg; Time between excision and freezing: 16 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00497-21: Section location: Right Middle Lobe; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3N-00497-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -31 days; Initial weight: 193 mg; Time between excision and freezing: 16 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-00497-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -31 days; Method of sample procurement: Blood Draw.
